FM case AD834 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/ef68a080-e7c8-4c36-b920-35ab2a79856e

Female, 58.3 years: Carcinoma, NOS (ICD-O-3 8010/3). Sample type: Tumor.
